Surgical pathology report (de-identified scan), TCGA case TCGA-QM-A5NM, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site University of Oklahoma HSC, specimen TCGA-QM-A5NM-01A (Primary Tumor).

[page 1 of 6]
Specimen Inquiry

PATIENT:

LOC:

SPEC #:

CLINICAL HISTORY:

SPECIMEN/PROCEDURE:

1. LYMPH NODE, PARAAORTIC - LEFT
2. LYMPH NODE, ILIAC - LEFT COMMON
3. LYMPH NODE, PARAAORTIC - RIGHT
4. LYMPH NODE, ILIAC - RIGHT COMMON
5. LYMPH NODE - RIGHT OBTURATOR
6. LYMPH NODE, ILIAC - RIGHT EXTERNAL
7. LYMPH NODE - RIGHT HYPOGASTRIC
8. LYMPH NODE, ILIAC - LEFT EXTERNAL
9. LYMPH NODE - LEFT OBTURATOR
10. UTERUS - AND CERVIX, BILATERAL TUBES/OVARIES

ICD-8-3
Carcinoma/Mixed Mullerian
Tumor 8950/3
Site: Endometrium C54.1
Q4 4/12/13

IMPRESSION:

- 1) LYMPH NODE, LEFT PARA-AORTIC, BIOPSY:
. One benign lymph node (0/1).
- 2) LYMPH NODES, LEFT COMMON ILIAC, REGIONAL DISSECTION:
. Three benign lymph nodes (0/3).
- 3) LYMPH NODES, RIGHT PARA-AORTIC, REGIONAL DISSECTION:
. Three benign lymph nodes (0/3).
- 4) LYMPH NODE, RIGHT COMMON ILIAC, BIOPSY:
. One benign lymph node (0/1).
- 5) LYMPH NODES, RIGHT OBTURATOR, REGIONAL DISSECTION:
. Three benign lymph nodes (0/3).
- 6) LYMPH NODES, RIGHT EXTERNAL ILIAC, REGIONAL DISSECTION:
. Three benign lymph nodes (0/3).
- 7) LYMPH NODE, RIGHT HYPOGASTRIC, BIOPSY:
. Benign fibroadipose tissue; no lymph node identified.
- 8) LYMPH NODE, LEFT EXTERNAL ILIAC, BIOPSY:
. One benign lymph node (0/1).
- 9) LYMPH NODES, LEFT OBTURATION, REGIONAL DISSECTION:
. Three benign lymph nodes (0/3).
- 10) UTERUS WITH CERVIX, BILATERAL FALLOPIAN TUBES AND OVARIES, SIMPLE HYSTERECTOMY WITH BILATERAL SALPINGO-OOPHORECTOMY:
. ENDOMYOMETRIUM:

[page 2 of 6]
IMPRESSION: (continued)

- . Carcinosarcoma with heterologous elements (chondrosarcoma) limited to the endometrium (see tumor checklist).
- . Negative for vascular space invasion.
- . CERVIX:
- . Negative for malignancy.
- . BILATERAL OVARIES:
- . Negative for malignancy.
- . BILATERAL FALLOPIAN TUBES:
- . Negative for malignancy.

* Pathologic TNM (AJCC 7th Edition): pT1a NO

ENDOMETRIAL HYSTERECTOMY, WITH OR WITHOUT OTHER ORGANS OR TISSUE CASE SUMMARYSPECIMEN

Uterine corpus
Cervix
Right ovary
Left ovary
Right fallopian tube
Left fallopian tube

PROCEDURE

Simple hysterectomy
Bilateral salpingo-oophorectomy

LYMPH NODE SAMPLING

Performed

SPECIMEN INTEGRITY

Intact hysterectomy specimen

TUMOR SITE

Anterior endometrium

TUMOR SIZE

Greatest dimension: 11.1 x 2.2 x 1.7 cm

HISTOLOGIC TYPE

Carcinosarcoma (malignant mullerian mixed tumor)

MYOMETRIAL INVASION

Not identified

INVOLVEMENT OF CERVIX

Not involved

EXTENT OF INVOLVEMENT OF OTHER ORGANS

Right ovary
Not involved
Left ovary
Not involved
Right fallopian tube
Not involved
Left fallopian tube

[page 3 of 6]
IMPRESSION: (continued)

Not involved

MARGINS

Uninvolved by invasive carcinoma

LYMPH-VASCULAR INVASION

Not identified

PATHOLOGIC STAGING (pTNM)**PRIMARY TUMOR (pT)**

pT1a[IA]: Tumor limited to endometrium or invades less than one-half of the myometrium

REGIONAL LYMPH NODES (pN)

pN0: No regional lymph node metastasis

Pelvic lymph nodes:

Number examined: 14

Number involved: 0

Para-aortic lymph nodes:

Number examined: 8

Number involved: 0

DISTANT METASTASIS (pM)

Not applicable

ADDITIONAL PATHOLOGIC FINDINGS

None identified

ANCILLARY STUDIES

Specify: Immunohistochemistry

Pathologic TNM (AJCC 7th edition): pT1a N0

COMMENT:**SPECIAL STAINS/PROCEDURES:**

The following immunohistochemical stains were performed with appropriate positive and negative controls on block 10R:

Pancytokeratin:

Positive in carcinomatous component.

Vimentin:

Positive in sarcomatous component and focal carcinomatous component.

Myogenin:

[page 4 of 6]
SPEC #:

SPECIAL STAINS/PROCEDURES: (continued)

Negative in tumor cells.

Desmin:

Negative in tumor cells.

S-100:

Negative in tumor cells.

Smooth Muscle Actin:

Positive in few tumor cells.

GROSS DESCRIPTION:

1. Received in formalin labeled with the patient's name and left periaortic. Received is a 2.5 x 1.5 x 0.7 cm portion of slightly hemorrhagic yellow gold fibroadipose tissue. The specimen is dissected for possible lymph nodes, one possible lymph node is identified that is 1.5 x 0.7 x 0.5 cm. The specimens is submitted as follows:

CASSETTE 1A: One lymph node bisected

2. Received in formalin labeled with the patient's name and left common iliac. Received is a 3 x 2 x 0.9 cm aggregate of slightly hemorrhagic yellow gold fibroadipose tissue. The specimen is dissected for possible lymph nodes, 3 possible lymph nodes are identified ranging from 0.7-1.5 cm in greatest dimension. The specimens is submitted as follows:

CASSETTE 2A: One possible lymph node
CASSETTE 2B: One lymph node bisected
CASSETTE 2C: One lymph node bisected

3. Received in formalin labeled with the patient's name and right para-aortic. Received is a 3.7 x 1.5 x 0.6 cm portion of slightly hemorrhagic yellow gold fibroadipose tissue. The specimen is dissected for possible lymph nodes, 3 possible lymph nodes are identified ranging from 0.7-2 cm in greatest dimension. The specimens is submitted as follows:

CASSETTE 3A: One lymph node bisected
CASSETTE 3B: One lymph node bisected
CASSETTE 3C: One lymph node bisected

4. Received in formalin labeled with the patient's name and right common iliac. Received is a 3.5 x 2.4 x 1 cm aggregate of slightly hemorrhagic yellow gold fibroadipose tissue. The specimen is dissected for possible lymph nodes, one possible lymph node is identified that is 2.2 x 0.9 x 0.7 cm. The specimens is submitted as follows:

CASSETTE 4A: One lymph node bisected

5. Received in formalin labeled with the patient's name and right operator. Received is a 3 x 2.4 x 1.2 cm aggregate of slightly hemorrhagic yellow gold fibroadipose tissue. The specimen is dissected for possible lymph nodes, 3 possible lymph nodes are identified ranging from 1-1.5 cm in greatest dimension. The specimens is submitted as follows:

CASSETTE 5A: One lymph node bisected

** CONTINUED ON NEXT PAGE **

[page 5 of 6]
GROSS DESCRIPTION: (continued)

CASSETTE 5B: One lymph node bisected

CASSETTE 5C: One lymph node bisected

6. Received in formalin labeled with the patient's name and right external iliac lymph node. Received is a 5 x 3 x 1.2 cm portion of slightly hemorrhagic yellow gold fibroadipose tissue. The specimen is dissected for possible lymph nodes, 3 possible lymph nodes are identified ranging from 0.6-2 cm in greatest dimension. The specimens is submitted as follows:

CASSETTE 6A: One lymph node

CASSETTE 6B: One lymph node bisected

CASSETTE 6C: One lymph node bisected

7. Received in formalin labeled with the patient's name and right hypogastric. Received is a 1.5 x 1.2 x 0.2 cm aggregate of yellow gold lobular fibroadipose tissue. There are no lymph nodes grossly identifiable. The specimen is entirely submitted in cassette 7A.

8. Received in formalin labeled with the patient's name and left external iliac lymph node. Received is a 3.4 x 2.2 x 1.4 cm aggregate of slightly hemorrhagic yellow gold fibroadipose tissue. The specimen is dissected for possible lymph nodes, one possible lymph node is identified that is 2 x 0.8 x 0.5 cm. The specimens is submitted as follows:

CASSETTE 8A: One lymph node bisected

9. Received in formalin labeled with the patient's name and left operator lymph node. Received is a 4.7 x 1.9 x 1.2 cm portion of slightly hemorrhagic yellow gold fibroadipose tissue. The specimen is dissected for possible lymph nodes, 3 possible lymph nodes are identified ranging from 0.5-3.5 cm in greatest dimension. The specimens is submitted as follows:

CASSETTE 9A: 2 possible lymph nodes

CASSETTE 9B-9C: One lymph node bisected

10. Received fresh and labeled with the patient's name and "cervix, uterus, bilateral tubes and ovaries" is a 123 gram specimen including an unopened uterus (8.2 x 4.9 x 2.9 cm), right fallopian tube (4.9 cm in length, 0.5 cm in diameter), right ovary (2.0 x 1.1 x 0.7 cm), left fallopian tube (5.1 cm in length, 0.5 cm in diameter), and left ovary (2.0 x 1.0 x 0.6 cm). The exocervix (2.7 x 2.5 cm) is covered by smooth glistening white mucosa. The external os is circular and measures 0.7 cm in diameter. The endocervical canal (2.5 cm in length) has a tan herringbone mucosa. The endometrial cavity (2.9 cm from cornu to cornu, 3.9 cm in length) has a tan-pink hemorrhagic endometrial lining. Filling the endometrial cavity is a polypoid lobulated yellow-tan soft mass (11.1 x 2.2 x 1.7 cm) with interspersed firmer white ill-defined foci. The mass is attached to the anterior lower uterine segment endometrium. A 1.8 x 1.6 cm area of heaped up irregular endometrium is superior to the mass attachment site (towards the fundus). The myometrium measures 1.5 cm in maximum thickness. The serosa is shiny and glistening without adhesions. The fallopian tubes are patent and have fimbriated ends. Both ovaries have a smooth white outer surface and white-yellow grossly unremarkable parenchyma.

INK CODE:

Black: Posterior uterus

Blue: Anterior uterus

[page 6 of 6]
SPEC #:

GROSS DESCRIPTION: (continued)

CASSETTE SUMMARY:

10A: Posterior cervix and lower uterine segment
10B: Posterior lower uterine segment
10C-10E: Posterior endomyometrium, representative sections from lower uterine segment to fundus
10G: Anterior cervix and lower uterine segment
10H: Anterior lower uterine segment
10J-10L: Anterior endomyometrium with mass attachment site, representative sections
10M, 10N: Anterior endomyometrium with heaped up endometrium near fundus
10P-10T: Mass, representative sections
10U, 10V: Right ovary, trisected and entirely submitted
10W, 10X: Right fallopian tube, serially sectioned and entirely submitted
10Y, 10Z: Left fallopian tube, serially sectioned and entirely submitted
10AA, 10AB: Left ovary, trisected and entirely submitted
10RT: Mass, representative section
10RN: Fallopian tube, representative section

COPIES TO:

Undefined Provider

CPT Codes:

ACTIN-88342, IHC DESMIN-88342, IHC S-100-88342, IHC VIMENTIN-88342,
LYMPH NODE, REGIONAL RESECT/88307/5, UTERUS W/NO ADNEXAE, TUMOR-88309,
IHC KERATIN COCKTAIL-88342, IHC MYOGENIN-88342, LYMPH NODE BIOPSY/88305/4, NEG MAB CONTROL

ICD9 Codes:

182.0

Electronically Signed by:

** END OF REPORT **

Source: NCI Genomic Data Commons file 74023c4f-43c5-4838-98ba-88f3d142ca90 (TCGA-QM-A5NM.9AEE4573-A7FC-47A8-88AF-CFE1EB9CF74B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).